Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4331, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4331-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Left renal mass.

Specimens Submitted:

1: SP: Lt. posterior mid-pole renal mass

2: SP: Peri-nephric fat left

DIAGNOSIS:

- 1) KIDNEY, POSTERIOR MID-POLE, LEFT, PARTIAL RESECTION:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE III/IV. THE PATTERN OF GROWTH IS ACINAR. THE TUMOR GREATEST DIAMETER IS 3.7 CM. THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE TUMOR IS WITHIN 1.0 MM OF RENAL PARENCHYMAL MARGIN. THE NON-NEOPLASTIC KIDNEY SHOWS CHRONIC PYELONEPHRITIS, NEPHROSCLEROSIS AND PAPILLARY ADENOMA. THE ADRENAL GLAND IS NOT SUBMITTED.
- 2) SOFT TISSUE, LEFT, PERI-NEPHRIC FAT; EXCISION:
- BENIGN ADIPOSE TISSUE.

Gross Description:

1) The specimen is received fresh for frozen section, labeled, "Left posterior mid-pole renal mass, stitch marks deep margin". It consists of portion of rectum specimen measuring 5.5 x 5.0 x 3.5 cm with a stitch designating the deep margin which is inked black. Sectioning reveals a well-defined capsular tumor measuring 3.7 x 3.7 x 3.0 cm. The cut surface of the specimen is hemorrhagic and bright yellow in color. Representative sections of the specimen are submitted for frozen. The margin opposite to the staple and margin designated as deep is inked yellow. The mass is situated grossly 0.3 cm from the stapled margin and 0.7 cm from margin opposite to it. Representative sections of the tumor including inked margin are submitted.

Summary of Sections:

FSC - frozen section control

U - undesignated

2) The specimen is received fresh, labeled, "Peri-nephric fat left". It consists of a piece of adipose tissue measuring 25.0 x 18 x 4.0 cm. Sectioning reveals a discrete mass. Representative sections of the specimen are submitted.

Summary of Sections:

U - undesignated

Summary of Sections:

[page 2 of 2]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Part 1: SP: Lt. posterior mid-pole renal mass [REDACTED]

Block	Sect. Site	PCs
1	FSC	1
9	U	9

Part 2: SP: Peri-nephric fat left [REDACTED]

Block	Sect. Site	PCs
3	U	3

Intraoperative Consultation:

Note: the diagnosis given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA (CLOSE WITHIN 1.0 MM) MARGIN MARKED WITH STITCH. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
- [REDACTED]

Source: NCI Genomic Data Commons file e45f34ec-77b4-4c25-915a-01ac3df65bd1 (TCGA-BP-4331.7A8E6BF9-0756-49BF-8911-AA43247E1544.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).